Somatic mutation profile of tumor specimen C3N-01902-05 (aliquot CPT0181260006) from CPTAC case C3N-01902, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.0 years (23,391 days).
Specimen C3N-01902-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 749ca300-f95f-40a5-b093-b309919e2756.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01902-31 (Blood Derived Normal), aliquot CPT0181310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/531f9214-3438-4363-8b82-f7698b1c5991

The open-access MAF lists 122 somatic variants for this specimen: 83 protein-altering or splice-affecting, 24 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 24, Frame Shift Del 11, Intron 7, Nonsense Mutation 4, 5'Flank 3, Splice Site 3, Frame Shift Ins 2, 5'UTR 2, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD10 | c.2714G>A p.R905Q | Missense Mutation (SNP) | VAF 90/289 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs773398824; called by muse, mutect2, varscan2
- ADH1B | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 210/742 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1473501011; called by muse, mutect2, varscan2
- ALDOB | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 204/730 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1243910791; called by muse, mutect2, varscan2
- APOB | c.6790G>C p.E2264Q | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV51935408, COSV51942133; called by muse, mutect2, varscan2
- BST2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 101/372 reads (27%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.989); catalogued as rs200644366; called by muse, mutect2, varscan2
- CDH18 | c.1148T>A p.F383Y | Missense Mutation (SNP) | VAF 45/542 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56938096; called by muse, mutect2
- CLSPN | c.2273A>G p.D758G | Missense Mutation (SNP) | VAF 98/335 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs1364565222; called by muse, mutect2, varscan2
- CRTC1 | c.65C>A p.A22E | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867448696; called by muse, varscan2
- ETV4 | c.956-2A>G p.X319_splice | Splice Site (SNP) | VAF 19/88 reads (22%) | catalogued as rs1282488878; called by muse, mutect2
- FCAR | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 107/399 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62029544; called by muse, mutect2, varscan2
- GABBR2 | c.2027G>A p.W676* | Nonsense Mutation (SNP) | VAF 13/338 reads (4%) | catalogued as COSV99412083; called by muse, mutect2
- H2BW2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 88/122 reads (72%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1254379008; called by muse, varscan2
- HRNR | c.3260C>T p.S1087L | Missense Mutation (SNP) | VAF 293/1077 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs547893856, COSV64258766, COSV64261974; called by muse, mutect2, varscan2
- MYO18A | c.3905G>C p.R1302P | Missense Mutation (SNP) | VAF 86/298 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62862456; called by muse, mutect2, varscan2
- MYOCD | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs370289662; called by muse, mutect2, varscan2
- PRKD1 | c.2074G>C p.V692L | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV59559687, COSV99045699; called by muse, mutect2, varscan2
- PTPRB | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 145/490 reads (30%) | catalogued as rs1323666538; called by muse, mutect2, varscan2
- RBM23 | c.256C>T p.R86W (on ENST00000359890 / NM_001077351.2; = p.R70W on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.432); catalogued as rs754235100, COSV57126948; called by muse, mutect2, varscan2
- RDH13 | c.280C>G p.R94G (on ENST00000415061 / NM_001145971.2; = p.R23G on NM_138412.4) | Missense Mutation (SNP) | VAF 14/421 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs774070838; called by muse, mutect2
- SH2D4B | c.536T>C p.I179T | Missense Mutation (SNP) | VAF 115/325 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs761444188; called by muse, mutect2, varscan2
- TAS2R43 | c.677A>C p.K226T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs1332679439; called by muse, varscan2
- TPP2 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101060496; called by muse, mutect2, varscan2
- TUT1 | c.2344C>A p.R782S | Missense Mutation (SNP) | VAF 133/417 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53469375; called by muse, mutect2, varscan2
- UNC119B | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs748180339, COSV100763488; called by muse, mutect2, varscan2
- VHL | c.407_408insA p.F136Lfs*8 | Frame Shift Ins (INS) | VAF 143/383 reads (37%) | catalogued as COSV56573956; called by mutect2, pindel, varscan2
- ZNF331 | c.219T>G p.D73E | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs935482287, COSV53476931; called by muse, mutect2, varscan2
- ACAD9 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BIRC6 | c.8363del p.A2788Vfs*28 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- CCDC146 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 66/259 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH5 | c.135_148del p.Q45Hfs*8 | Frame Shift Del (DEL) | VAF 85/447 reads (19%) | called by mutect2, pindel, varscan2
- CRTC1 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- CSMD2 | c.8894G>A p.G2965D | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCTN1 | c.989A>T p.E330V | Missense Mutation (SNP) | VAF 22/754 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2
- DOK3 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 230/665 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- E4F1 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 74/235 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- EDEM1 | c.411_417delinsA p.M137_V139delinsI | In Frame Del (DEL) | VAF 48/209 reads (23%) | called by pindel, varscan2*
- FAM135A | c.2514_2518del p.S839Kfs*7 (on ENST00000370479 / NM_001351599.1; = p.S626Kfs*7 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | called by mutect2, pindel, varscan2
- FAM186A | c.1748G>C p.R583T | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXL18 | c.211A>T p.T71S | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- FER1L5 | c.5088del p.L1697Wfs*80 (on ENST00000623019; = p.L1670Wfs*71 on NM_001293083.2) | Frame Shift Del (DEL) | VAF 123/512 reads (24%) | called by mutect2, pindel, varscan2
- FRAS1 | c.7561A>T p.K2521* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- GGH | c.715T>A p.Y239N | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GREB1L | c.5620T>C p.C1874R | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRK2 | c.1744T>C p.Y582H | Missense Mutation (SNP) | VAF 144/557 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- GTPBP2 | c.297G>C p.E99D | Missense Mutation (SNP) | VAF 105/382 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- HIF1A | c.1814del p.T605Ifs*20 | Frame Shift Del (DEL) | VAF 106/427 reads (25%) | called by mutect2, pindel, varscan2
- IGSF1 | c.3422C>G p.T1141S | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- JMJD4 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 82/360 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- LMO7 | c.886A>C p.N296H (on ENST00000357063; = p.N311H on NM_005358.5) | Missense Mutation (SNP) | VAF 87/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPO | c.2116_2117insT p.P706Lfs*119 | Frame Shift Ins (INS) | VAF 90/356 reads (25%) | called by mutect2, pindel, varscan2
- LUZP2 | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAMDC4 | c.1225G>T p.G409W | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP2 | c.3632C>G p.S1211C | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- MINDY3 | c.861C>A p.H287Q | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MINPP1 | c.847_859del p.V283Pfs*21 | Frame Shift Del (DEL) | VAF 44/313 reads (14%) | called by mutect2, pindel, varscan2
- MR1 | c.908A>G p.K303R | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MTHFD1L | c.2685C>A p.Y895* | Nonsense Mutation (SNP) | VAF 67/223 reads (30%) | called by muse, mutect2, varscan2
- NCAPG2 | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 100/358 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NCOA6 | c.3464T>A p.V1155E | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- NR1D2 | c.932G>C p.C311S | Missense Mutation (SNP) | VAF 93/189 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- OCRL | c.2249G>A p.C750Y | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2
- PLEKHG1 | c.1209C>G p.D403E | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRDM13 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 107/331 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RBCK1 | c.1289A>C p.Q430P (on ENST00000356286 / NM_031229.4; = p.Q388P on NM_006462.6) | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- RHBDD3 | c.1069T>C p.S357P | Missense Mutation (SNP) | VAF 95/493 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- RHOC | c.319T>A p.C107S | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RPS6KA4 | c.1764G>T p.E588D | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SCN2A | c.2025_2059del p.T676Lfs*32 | Frame Shift Del (DEL) | VAF 80/492 reads (16%) | called by mutect2, pindel
- SLC37A3 | c.1274_1275del p.T425Sfs*120 | Frame Shift Del (DEL) | VAF 152/568 reads (27%) | called by pindel, varscan2
- SLC44A3 | c.1546A>C p.K516Q (on ENST00000271227 / NM_001114106.3; = p.K468Q on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- SMPD4 | c.2351G>A p.G784E (on ENST00000409031 / NM_017951.4; = p.G755E on NM_017751.4) | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMPDL3A | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 130/460 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STX12 | c.790A>C p.I264L | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM101 | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM214 | c.578T>A p.L193Q | Missense Mutation (SNP) | VAF 102/375 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- TPBGL | c.951del p.I318Sfs*11 | Frame Shift Del (DEL) | VAF 63/311 reads (20%) | called by mutect2, pindel, varscan2
- TPGS2 | c.544T>G p.W182G | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRIP11 | c.838A>G p.I280V | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- UFD1 | c.169+1G>A p.X57_splice | Splice Site (SNP) | VAF 39/144 reads (27%) | called by muse, mutect2, varscan2
- UNC13C | c.5545_5546+1del p.X1849_splice | Splice Site (DEL) | VAF 60/199 reads (30%) | called by mutect2, pindel, varscan2
- ZADH2 | c.920del p.H307Lfs*10 | Frame Shift Del (DEL) | VAF 59/222 reads (27%) | called by mutect2, pindel, varscan2
- ZNF500 | c.743_759delinsG p.A248Gfs*19 | Frame Shift Del (DEL) | VAF 30/198 reads (15%) | called by pindel, varscan2*
- ZWILCH | c.891A>T p.E297D | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATP2B3 | c.2796C>T p.H932= | Silent (SNP) | VAF 18/460 reads (4%) | catalogued as rs782420658, COSV54844008; called by muse, mutect2
- CHST7 | c.735G>T p.P245= | Silent (SNP) | VAF 24/214 reads (11%) | catalogued as rs761724283; called by muse, mutect2, varscan2
- COL16A1 | c.2526C>T p.V842= | Silent (SNP) | VAF 61/219 reads (28%) | called by muse, mutect2, varscan2
- COL6A3 | c.4542G>T p.L1514= | Silent (SNP) | VAF 161/536 reads (30%) | called by muse, mutect2, varscan2
- EVPL | c.2838G>A p.R946= | Silent (SNP) | VAF 143/465 reads (31%) | called by muse, mutect2, varscan2
- FHIT | c.120G>T p.P40= | Silent (SNP) | VAF 13/147 reads (9%) | called by muse, mutect2
- GAREM1 | c.2394C>T p.D798= (on ENST00000269209 / NM_001242409.2; = p.D797= on NM_022751.3) | Silent (SNP) | VAF 36/261 reads (14%) | catalogued as rs200553110; called by muse, mutect2, varscan2
- HCFC1 | c.669G>A p.G223= | Silent (SNP) | VAF 85/291 reads (29%) | called by muse, mutect2, varscan2
- IGSF1 | c.3462C>T p.I1154= | Silent (SNP) | VAF 42/180 reads (23%) | called by muse, mutect2
- LILRA4 | c.378C>T p.S126= | Silent (SNP) | VAF 71/238 reads (30%) | catalogued as rs769153231, COSV52490469; called by muse, mutect2
- MAP3K21 | c.2994A>G p.S998= | Silent (SNP) | VAF 78/325 reads (24%) | called by muse, mutect2, varscan2
- NOS3 | c.1578C>A p.S526= | Silent (SNP) | VAF 104/407 reads (26%) | catalogued as COSV52494565; called by muse, mutect2, varscan2
- NXNL2 | c.342C>T p.G114= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs527683762; called by muse, mutect2, varscan2
- OCRL | c.582T>G p.A194= | Silent (SNP) | VAF 342/423 reads (81%) | called by muse, mutect2, varscan2
- PRSS22 | c.684C>T p.A228= | Silent (SNP) | VAF 92/269 reads (34%) | catalogued as rs368817861; called by muse, mutect2, varscan2
- RASSF6 | c.894C>T p.R298= (on ENST00000342081 / NM_201431.2; = p.R266= on NM_177532.5) | Silent (SNP) | VAF 49/151 reads (32%) | called by muse, mutect2, varscan2
- RBM42 | c.537C>T p.G179= | Silent (SNP) | VAF 83/232 reads (36%) | catalogued as rs776396407, COSV99387327; called by muse, mutect2, varscan2
- SEMA4B | c.1986C>A p.G662= | Silent (SNP) | VAF 53/187 reads (28%) | called by muse, mutect2, varscan2
- SYNE2 | c.12705A>G p.T4235= | Silent (SNP) | VAF 217/785 reads (28%) | called by muse, mutect2, varscan2
- TECTA | c.1110C>T p.R370= | Silent (SNP) | VAF 111/473 reads (23%) | catalogued as COSV50689197; called by muse, mutect2, varscan2
- UBQLNL | c.348G>A p.L116= | Silent (SNP) | VAF 52/172 reads (30%) | catalogued as COSV66494349; called by muse, mutect2, varscan2
- WARS2 | c.534T>A p.V178= | Silent (SNP) | VAF 70/198 reads (35%) | called by muse, mutect2, varscan2
- WDR5 | c.171A>T p.G57= | Silent (SNP) | VAF 70/237 reads (30%) | called by muse, mutect2, varscan2
- ZNF703 | c.1269G>A p.L423= | Silent (SNP) | VAF 14/336 reads (4%) | called by muse, mutect2
- ANKRD42 | chr11:83193787 del AGAA | 5'Flank (DEL) | VAF 36/140 reads (26%) | called by mutect2, pindel, varscan2
- ATP2A1 | c.-112A>T | 5'UTR (SNP) | VAF 38/114 reads (33%) | called by muse, mutect2, varscan2
- CABP1 | c.655-3871G>A | Intron (SNP) | VAF 47/144 reads (33%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009411 A>C | 5'Flank (SNP) | VAF 43/141 reads (30%) | called by muse, mutect2, varscan2
- GLP2R | c.1056+3816C>A | Intron (SNP) | VAF 85/316 reads (27%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1636G>T | RNA (SNP) | VAF 120/464 reads (26%) | called by muse, mutect2, varscan2
- KRTAP5-11 | chr11:71579763 ins AGCAGGACCTGCAGCAGCTGGACTGGGAGG | 3'Flank (INS) | VAF 11/118 reads (9%) | called by muse*, mutect2, varscan2*
- LUC7L3 | c.99+4018G>T | Intron (SNP) | VAF 21/68 reads (31%) | called by mutect2, varscan2
- NT5C3A | c.-15A>G | 5'UTR (SNP) | VAF 31/809 reads (4%) | called by muse, mutect2
- RARB | c.179-32456del | Intron (DEL) | VAF 26/66 reads (39%) | catalogued as COSV100412442; called by mutect2, pindel, varscan2
- RBMX | c.109+62G>C | Intron (SNP) | VAF 78/212 reads (37%) | catalogued as rs980644696, COSV57808891; called by muse, mutect2, varscan2
- RPL7A | c.496-127del | Intron (DEL) | VAF 69/252 reads (27%) | catalogued as rs1213004869; called by mutect2, pindel, varscan2
- SRCIN1 | c.2829+55C>T | Intron (SNP) | VAF 7/183 reads (4%) | catalogued as rs749211680; called by muse, mutect2
- TMEM220 | c.*34T>G | 3'UTR (SNP) | VAF 50/124 reads (40%) | called by muse, mutect2, varscan2
- ZNF862 | chr7:149833809 G>C | 5'Flank (SNP) | VAF 80/230 reads (35%) | catalogued as rs999782929; called by muse, mutect2
